Somatic mutation profile of tumor specimen 0DBE3K from CCDI case PBBKWB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,774 days).
Specimen 0DBE3K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef56a134-65ab-42e3-9a71-1c89b19d47d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBE2I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ab31fb-431f-4852-a8c0-30bbf2f207c6

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 2, 5'UTR 2, 3'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP251 | c.1404del p.K469Sfs*71 | Frame Shift Del (DEL) | VAF 196/1290 reads (15%) | catalogued as COSV99996524; called by mutect2, varscan2
- HEXD | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 235/975 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs754273625; called by muse, mutect2, varscan2
- MUC16 | c.32888C>T p.P10963L | Missense Mutation (SNP) | VAF 41/552 reads (7%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as rs374230290; called by muse, mutect2
- MUSK | c.913+2T>C p.X305_splice | Splice Site (SNP) | VAF 213/486 reads (44%) | catalogued as rs757030913; called by muse, mutect2, varscan2
- MYPN | c.519T>G p.I173M | Missense Mutation (SNP) | VAF 448/1433 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs769771296; called by muse, mutect2, varscan2
- NBPF3 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 329/939 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs1199489486; called by muse, mutect2, varscan2
- RSPH6A | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 155/256 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs756241163, COSV55575124; called by muse, mutect2, varscan2
- ADCY6 | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR2 | c.799A>C p.I267L | Missense Mutation (SNP) | VAF 20/704 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2
- MAGI1 | c.3622G>T p.V1208L (on ENST00000402939 / NM_001033057.2; = p.V1237L on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 645/1224 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SLC17A8 | c.884C>G p.A295G | Missense Mutation (SNP) | VAF 222/696 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 42/1360 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- TMPRSS11A | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 457/936 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HIGD1B | c.174C>T p.S58= | Silent (SNP) | VAF 84/1347 reads (6%) | called by muse, mutect2
- SPEG | c.2763G>A p.E921= | Silent (SNP) | VAF 64/365 reads (18%) | called by muse, mutect2, varscan2
- SPTBN5 | c.8107C>T p.L2703= | Silent (SNP) | VAF 161/519 reads (31%) | catalogued as rs377622495; called by muse, mutect2, varscan2
- WNT3A | c.120C>T p.I40= | Silent (SNP) | VAF 49/670 reads (7%) | catalogued as COSV99470178; called by muse, mutect2
- CD33 | c.37+29G>A | Intron (SNP) | VAF 166/580 reads (29%) | catalogued as rs777876718; called by muse, mutect2
- SHROOM4 | c.-2G>T | 5'UTR (SNP) | VAF 84/195 reads (43%) | called by muse, mutect2, varscan2
- SPANXD | c.-23A>T | 5'UTR (SNP) | VAF 28/486 reads (6%) | called by muse, mutect2
- SPICE1 | c.*50T>A | 3'UTR (SNP) | VAF 154/334 reads (46%) | called by muse, mutect2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 24/564 reads (4%) | called by muse, mutect2
